Somatic mutation profile of tumor specimen ASCProject_0030_T1_WES (aliquot ASCProject_0030_T1_WES_1) from CMI case ASCProject_0030, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 30.8 years (11,264 days).
Specimen ASCProject_0030_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72ea75b7-3247-4eb1-b443-e834c54b8e76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0030_SALIVA (Saliva), aliquot ASCProject_0030_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5739929a-c20b-492a-92ba-db537adb715a

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR6B1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 25/253 reads (10%) | catalogued as rs745433880, COSV68770009; called by muse, mutect2
- PLCG1 | c.3493G>C p.D1165H | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54814749; called by muse, mutect2
- AGAP2 | c.2900T>A p.I967N (on ENST00000547588 / NM_001122772.2; = p.I611N on NM_014770.4) | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- NT5DC4 | c.314G>C p.S105T | Missense Mutation (SNP) | VAF 41/390 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SIX1 | c.361A>T p.I121F | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLRP10 | c.1279C>T p.L427= | Silent (SNP) | VAF 30/303 reads (10%) | called by muse, mutect2
- SYT14 | c.1500A>G p.T500= | Silent (SNP) | VAF 40/480 reads (8%) | called by muse, mutect2
